Somatic mutation profile of tumor specimen TCGA-YS-AA4M-01A (aliquot TCGA-YS-AA4M-01A-11D-A39R-32) from TCGA case TCGA-YS-AA4M, project TCGA-MESO (Mesothelioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mesothelioma, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 66.2 years (24,176 days).
Specimen TCGA-YS-AA4M-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2f22ccdd-21aa-4a5e-a692-c8982049cffc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-YS-AA4M-10A (Blood Derived Normal), aliquot TCGA-YS-AA4M-10A-01D-A39U-32; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e2a60049-2dfc-4553-a373-b6cbaabdc1db

The open-access MAF lists 17 somatic variants for this specimen: 14 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 12, Silent 3, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FCHO2 | c.1930G>A p.E644K | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as rs200271658, COSV100530771; called by muse, mutect2, varscan2
- H1-4 | c.40C>T p.P14S | Missense Mutation (SNP) | VAF 32/170 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.045); catalogued as rs1400921386; called by muse, mutect2, varscan2
- MPEG1 | c.894C>A p.N298K | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs374800011; called by mutect2, varscan2
- NF2 | c.70del p.V24* | Frame Shift Del (DEL) | VAF 33/267 reads (12%) | catalogued as COSV58519881; called by mutect2, pindel, varscan2
- OR13C8 | c.329C>A p.T110K | Missense Mutation (SNP) | VAF 13/141 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); catalogued as COSV100622939; called by muse, mutect2
- PXDN | c.2989C>T p.R997C | Missense Mutation (SNP) | VAF 18/196 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748237720, COSV99414457; called by muse, mutect2
- SPATS2L | c.1388G>A p.G463E | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.01); catalogued as rs1225722106, COSV62348172; called by muse, mutect2, varscan2
- TMEM74B | c.210G>T p.E70D | Missense Mutation (SNP) | VAF 11/206 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); catalogued as COSV101121988; called by muse, mutect2
- CR2 | c.2350C>T p.P784S | Missense Mutation (SNP) | VAF 11/121 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.73); called by muse, mutect2
- GPER1 | c.127G>A p.A43T | Missense Mutation (SNP) | VAF 12/220 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0.007); called by muse, mutect2
- HEATR3 | c.700G>T p.E234* | Nonsense Mutation (SNP) | VAF 11/82 reads (13%) | called by muse, mutect2, varscan2
- SCNN1G | c.1643A>C p.E548A | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC9A4 | c.1141T>A p.W381R | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TAS2R4 | c.687G>A p.M229I | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT tolerated (0.44); PolyPhen benign (0.005); called by muse, mutect2
- GDF1 | c.240G>A p.R80= | Silent (SNP) | VAF 20/165 reads (12%) | called by muse, mutect2, varscan2
- KCNK3 | c.171C>A p.G57= | Silent (SNP) | VAF 12/151 reads (8%) | catalogued as rs763871946; called by muse, mutect2
- TGFBRAP1 | c.1632C>T p.A544= | Silent (SNP) | VAF 11/165 reads (7%) | called by muse, mutect2
